Somatic mutation profile of tumor specimen TCGA-FF-A7CQ-01A (aliquot TCGA-FF-A7CQ-01A-11D-A382-10) from TCGA case TCGA-FF-A7CQ, project TCGA-DLBC (Lymphoid Neoplasm Diffuse Large B-cell Lymphoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Diffuse large B-cell lymphoma, NOS; Tissue or organ of origin: Lymph nodes of head, face and neck; Age at diagnosis: 74.6 years (27,255 days).
Specimen TCGA-FF-A7CQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cdad7d75-a34b-4092-9bc2-1d1e8e3e180b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FF-A7CQ-10A (Blood Derived Normal), aliquot TCGA-FF-A7CQ-10A-01D-A385-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4834e6af-c924-4a35-b868-273e50117876

The open-access MAF lists 139 somatic variants for this specimen: 106 protein-altering or splice-affecting, 31 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 86, Silent 31, Nonsense Mutation 9, Splice Site 4, Frame Shift Ins 4, Frame Shift Del 1, Splice Region 1, 3'Flank 1, In Frame Del 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FOXC1 | c.141C>G p.Y47* | Nonsense Mutation (SNP) | VAF 9/30 reads (30%) | catalogued as rs372857241, CM152121, COSV101083321; ClinVar: pathogenic; called by muse, varscan2
- ADAMTS1 | c.896G>T p.R299L | Missense Mutation (SNP) | VAF 38/132 reads (29%) | SIFT tolerated (0.48); PolyPhen benign (0.023); catalogued as COSV99536291; called by muse, mutect2, varscan2
- AKR1B15 | c.621A>T p.K207N | Missense Mutation (SNP) | VAF 38/87 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.575); catalogued as COSV101423389; called by muse, mutect2, varscan2
- ALOXE3 | c.1498G>A p.V500I | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.632); catalogued as rs121434232, CM020012, COSV100559771; called by muse, mutect2, varscan2
- ARFGEF3 | c.196C>A p.Q66K | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.952); catalogued as COSV99293997; called by muse, mutect2, varscan2
- ARHGEF5 | c.683A>G p.Q228R | Missense Mutation (SNP) | VAF 28/144 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV99282927; called by muse, varscan2
- AUP1 | c.51G>A p.R17= | Splice Region (SNP) | VAF 19/87 reads (22%) | catalogued as rs1188740629, COSV99239769; called by muse, mutect2, varscan2
- BAAT | c.889C>T p.R297C | Missense Mutation (SNP) | VAF 28/163 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.809); catalogued as rs752255786, COSV52291557; called by muse, mutect2, varscan2
- BTG2 | c.172A>C p.K58Q | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.093); catalogued as COSV99305839; called by muse, mutect2, varscan2
- CABCOCO1 | c.343G>A p.E115K | Missense Mutation (SNP) | VAF 52/144 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1369670991, COSV57593175; called by muse, mutect2, varscan2
- CAVIN2 | c.1076C>T p.A359V | Missense Mutation (SNP) | VAF 40/144 reads (28%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); catalogued as rs1245900077, COSV100414238; called by muse, mutect2, varscan2
- CCDC178 | c.244C>T p.R82* | Nonsense Mutation (SNP) | VAF 39/123 reads (32%) | catalogued as rs1462269116, COSV100285401; called by muse, mutect2, varscan2
- CCDC47 | c.904C>G p.L302V | Missense Mutation (SNP) | VAF 37/161 reads (23%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.448); catalogued as COSV99854214; called by muse, mutect2, varscan2
- CD79B | c.587A>G p.Y196C | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1443292790, COSV50076054, COSV50076156, COSV50076492; called by muse, mutect2, varscan2
- CDH15 | c.2434C>T p.R812W | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs750047641, COSV57024135; called by muse, mutect2
- CDH20 | c.1279A>C p.I427L | Missense Mutation (SNP) | VAF 38/235 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.124); catalogued as COSV99405770; called by muse, mutect2, varscan2
- CDK13 | c.1001G>T p.S334I | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV99475724; called by muse, mutect2
- CPAMD8 | c.2260C>T p.Q754* (on ENST00000651564; = p.Q707* on NM_015692.5) | Nonsense Mutation (SNP) | VAF 11/39 reads (28%) | catalogued as COSV99359514; called by muse, mutect2, varscan2
- DGKD | c.2355T>A p.D785E (on ENST00000264057 / NM_152879.3; = p.D741E on NM_003648.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.085); catalogued as COSV99896734; called by muse, mutect2, varscan2
- DOCK3 | c.2780C>T p.A927V | Missense Mutation (SNP) | VAF 57/240 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.154); catalogued as rs766088466, COSV56522340; called by muse, mutect2, varscan2
- DSPP | c.543A>T p.E181D | Missense Mutation (SNP) | VAF 40/118 reads (34%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.048); catalogued as COSV99217562; called by muse, mutect2, varscan2
- EFHB | c.701G>A p.G234E | Missense Mutation (SNP) | VAF 39/118 reads (33%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV99859784; called by muse, mutect2, varscan2
- ELAVL1 | c.179G>A p.S60N | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.265); catalogued as COSV100688405; called by muse, mutect2, varscan2
- EPS8L1 | c.1150G>A p.D384N (on ENST00000201647 / NM_133180.3; = p.D257N on NM_017729.3) | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV99136608; called by muse, mutect2, varscan2
- FAT4 | c.5122G>A p.D1708N | Missense Mutation (SNP) | VAF 25/117 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.2); catalogued as COSV101272506; called by muse, mutect2, varscan2
- FEM1B | c.1810G>A p.A604T | Missense Mutation (SNP) | VAF 25/104 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.186); catalogued as COSV100183699; called by muse, mutect2, varscan2
- FKBP5 | c.71A>C p.D24A | Missense Mutation (SNP) | VAF 106/259 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.044); catalogued as COSV100616270; called by muse, mutect2, varscan2
- FOXC1 | c.98C>T p.A33V | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.796); catalogued as rs771450858, COSV101083320; called by muse, varscan2
- GAL3ST1 | c.841C>T p.R281C | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100143138; called by muse, mutect2, varscan2
- H1-4 | c.490G>A p.A164T | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT tolerated (0.91); PolyPhen possibly damaging (0.665); catalogued as rs201935674, COSV56799837, COSV56800144, COSV99175288; called by muse, mutect2, varscan2
- H2AC13 | c.85G>A p.G29S | Missense Mutation (SNP) | VAF 18/226 reads (8%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.541); catalogued as COSV100704404; called by muse, mutect2
- H2BC4 | c.218G>A p.R73H | Missense Mutation (SNP) | VAF 11/104 reads (11%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.019); catalogued as rs768236825, COSV100019962, COSV58415099; called by muse, mutect2, varscan2
- HS6ST3 | c.538G>A p.G180S | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100940934; called by muse, mutect2, varscan2
- IGHG1 | c.797G>A p.S266N | Missense Mutation (SNP) | VAF 50/180 reads (28%) | SIFT tolerated (0.43); PolyPhen benign (0.018); catalogued as rs751791072; called by muse, mutect2, varscan2
- IGHV1-69 | c.152A>C p.Y51S | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.119); catalogued as rs140392997; called by mutect2, varscan2
- IL22RA2 | c.575dup p.N192Kfs*9 | Frame Shift Ins (INS) | VAF 48/208 reads (23%) | catalogued as rs756450081; called by mutect2, varscan2
- INTS12 | c.47C>T p.A16V | Missense Mutation (SNP) | VAF 26/105 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV100415851; called by muse, mutect2, varscan2
- IRF4 | c.54C>G p.S18R | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV66704796, COSV66704913; called by muse, mutect2, varscan2
- ITGB4 | c.1081G>A p.E361K | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0.178); catalogued as COSV99564267; called by muse, mutect2, varscan2
- ITPR2 | c.1975C>T p.P659S | Missense Mutation (SNP) | VAF 29/126 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.431); catalogued as COSV101190049; called by muse, mutect2, varscan2
- JCHAIN | c.230C>T p.S77L | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV99636492; called by muse, mutect2, varscan2
- KCNT2 | c.301A>T p.S101C | Missense Mutation (SNP) | VAF 50/216 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.474); catalogued as COSV99654835, COSV99655778; called by muse, mutect2, varscan2
- KLHL14 | c.289C>T p.Q97* | Nonsense Mutation (SNP) | VAF 35/190 reads (18%) | catalogued as COSV100809073; called by muse, varscan2
- KLHL14 | c.268C>T p.Q90* | Nonsense Mutation (SNP) | VAF 69/164 reads (42%) | catalogued as COSV100809076; called by muse, varscan2
- LRIT2 | c.1199C>T p.S400L | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.67); PolyPhen benign (0.028); catalogued as rs371479420; called by muse, mutect2, varscan2
- LRRC7 | c.2030T>C p.I677T (on ENST00000651989 / NM_001370785.2; = p.I644T on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 43/144 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV99227877; called by muse, mutect2, varscan2
- MAEA | c.683C>T p.A228V (on ENST00000303400 / NM_001017405.3; = p.A187V on NM_005882.5) | Missense Mutation (SNP) | VAF 39/115 reads (34%) | SIFT tolerated (0.5); PolyPhen benign (0.065); catalogued as COSV99295548; called by muse, mutect2, varscan2
- MAGEL2 | c.3559C>T p.R1187* | Nonsense Mutation (SNP) | VAF 26/83 reads (31%) | catalogued as rs368965952, COSV100045884, COSV100046025; called by muse, mutect2, varscan2
- MMEL1 | c.1500+1G>T p.X500_splice | Splice Site (SNP) | VAF 26/101 reads (26%) | catalogued as COSV99984008; called by muse, mutect2, varscan2
- MPEG1 | c.1642G>A p.D548N | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.018); catalogued as COSV99915591; called by muse, mutect2, varscan2
- MTNR1B | c.166G>A p.V56M | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.068); catalogued as rs148309052; called by muse, mutect2, varscan2
- MUC16 | c.41696G>T p.R13899M | Missense Mutation (SNP) | VAF 27/108 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV101109955; called by muse, mutect2, varscan2
- MYH14 | c.1559G>A p.R520H | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs777311841, COSV99223237; called by muse, mutect2, varscan2
- NFYA | c.815A>G p.Y272C | Missense Mutation (SNP) | VAF 50/119 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100399719; called by muse, mutect2, varscan2
- NLRP9 | c.460G>A p.D154N | Missense Mutation (SNP) | VAF 39/133 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.348); catalogued as COSV60460467; called by muse, mutect2, varscan2
- NPAS1 | c.158C>T p.A53V | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101496919; called by muse, mutect2, varscan2
- OPCML | c.456T>G p.S152R | Missense Mutation (SNP) | VAF 28/142 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV100102689; called by muse, mutect2, varscan2
- OR2L8 | c.144C>G p.I48M | Missense Mutation (SNP) | VAF 92/340 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100594039, COSV61726490; called by muse, mutect2, varscan2
- OR7G1 | c.196C>G p.L66V | Missense Mutation (SNP) | VAF 38/128 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV99528646; called by muse, mutect2, varscan2
- OR8H1 | c.894T>A p.N298K | Missense Mutation (SNP) | VAF 45/194 reads (23%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as COSV100477195; called by muse, mutect2, varscan2
- PCDH7 | c.1182dup p.K395Qfs*10 | Frame Shift Ins (INS) | VAF 18/83 reads (22%) | catalogued as rs1185137028; called by mutect2, pindel, varscan2
- PHF20 | c.943T>G p.Y315D | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.014); catalogued as COSV100180422; called by muse, mutect2, varscan2
- PIM1 | c.41C>T p.A14V | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.05); catalogued as COSV100998700; called by muse, varscan2
- PIM1 | c.65C>T p.A22V | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT tolerated (0.58); PolyPhen benign (0.02); catalogued as COSV100998702; called by muse, varscan2
- PIM1 | c.143G>A p.G48D | Missense Mutation (SNP) | VAF 17/96 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.815); catalogued as rs758586647, COSV65164997; called by muse, varscan2
- PIM1 | c.248G>A p.G83D | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.076); catalogued as COSV65164544; called by muse, varscan2
- PIM1 | c.259C>T p.P87S | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV65165377; called by muse, varscan2
- PLCB1 | c.104C>A p.S35* | Nonsense Mutation (SNP) | VAF 58/253 reads (23%) | catalogued as COSV100571438; called by muse, mutect2, varscan2
- PLXNB2 | c.3362A>T p.K1121M | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.184); catalogued as rs769207954, COSV100834137; called by muse, mutect2, varscan2
- POSTN | c.1073T>C p.I358T | Missense Mutation (SNP) | VAF 52/197 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101123297; called by muse, varscan2
- PPP1R16B | c.457C>G p.L153V | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as COSV100239630; called by mutect2, varscan2
- PPP2R2B | c.960+2T>G p.X320_splice (on ENST00000394409; = p.X386_splice on NM_181674.2) | Splice Site (SNP) | VAF 34/124 reads (27%) | catalogued as COSV100355161; called by muse, mutect2, varscan2
- PPP2R2C | c.1088G>A p.R363H | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT tolerated (0.24); PolyPhen benign (0.058); catalogued as rs763404513, COSV100160476; called by muse, mutect2, varscan2
- PTPN14 | c.1675C>T p.L559F | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.994); catalogued as COSV100872745; called by muse, mutect2, varscan2
- RFX2 | c.763C>T p.R255W | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1192487690, COSV100353627; called by muse, mutect2, varscan2
- SHANK2 | c.3961G>A p.A1321T | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as rs555445178, COSV99574783; called by muse, mutect2, varscan2
- SRGAP1 | c.1457A>C p.K486T | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.081); catalogued as COSV100754856; called by muse, mutect2, varscan2
- STAP2 | c.556G>A p.G186S | Missense Mutation (SNP) | VAF 32/103 reads (31%) | SIFT tolerated (0.97); PolyPhen benign (0.003); catalogued as rs757979984, COSV99696858; called by muse, mutect2, varscan2
- STOML2 | c.874G>A p.D292N | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.09); catalogued as rs930593352, COSV99956788; called by muse, mutect2
- TAS2R30 | c.751A>C p.N251H | Missense Mutation (SNP) | VAF 40/162 reads (25%) | SIFT tolerated (0.36); PolyPhen benign (0.005); catalogued as COSV101115057; called by muse, varscan2
- TMSB4X | c.118C>T p.Q40* | Nonsense Mutation (SNP) | VAF 34/56 reads (61%) | catalogued as COSV66081150; called by muse, mutect2, varscan2
- TNF | c.280+1G>C p.X94_splice | Splice Site (SNP) | VAF 57/156 reads (37%) | catalogued as COSV101403212; called by muse, mutect2, varscan2
- TOGARAM1 | c.4558A>G p.N1520D | Missense Mutation (SNP) | VAF 29/98 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100818125; called by muse, mutect2, varscan2
- TTLL6 | c.2224A>G p.K742E (on ENST00000393382 / NM_001130918.3; = p.K435E on NM_173623.3) | Missense Mutation (SNP) | VAF 110/391 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.557); catalogued as COSV100938165; called by muse, mutect2, varscan2
- UBE2D3 | c.392G>A p.R131K | Missense Mutation (SNP) | VAF 130/477 reads (27%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.038); catalogued as COSV100414966; called by muse, mutect2, varscan2
- VCAM1 | c.1916C>T p.A639V | Missense Mutation (SNP) | VAF 44/153 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.053); catalogued as rs369761581; called by muse, mutect2, varscan2
- VPS13B | c.11935C>T p.P3979S | Missense Mutation (SNP) | VAF 56/152 reads (37%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as COSV99882003; called by muse, mutect2, varscan2
- VPS9D1 | c.1019C>A p.P340H | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV101232016; called by muse, mutect2
- WDR70 | c.1373G>A p.R458H | Missense Mutation (SNP) | VAF 42/180 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.03); catalogued as rs768879291, COSV99459245; called by muse, mutect2, varscan2
- XKR4 | c.899C>T p.A300V | Missense Mutation (SNP) | VAF 55/209 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs762026156, COSV59308833; called by muse, mutect2, varscan2
- ZNF648 | c.680C>T p.A227V | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as rs1022442823, COSV100374438, COSV100374545; called by muse, mutect2, varscan2
- ZNF677 | c.1452G>C p.E484D | Missense Mutation (SNP) | VAF 43/136 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.774); catalogued as COSV100448032, COSV61719244; called by muse, mutect2, varscan2
- CD58 | c.158_159del p.E53Gfs*9 | Frame Shift Del (DEL) | VAF 62/216 reads (29%) | called by pindel, varscan2
- CD79B | c.229_234del p.L77_W78del | In Frame Del (DEL) | VAF 19/65 reads (29%) | called by mutect2, pindel, varscan2
- EPS8L2 | c.1971_1974dup p.F659Afs*113 | Frame Shift Ins (INS) | VAF 25/94 reads (27%) | called by mutect2, pindel, varscan2
- IGHG1 | c.388C>T p.P130S | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.798); called by muse, mutect2, varscan2
- IGHG2 | c.865C>T p.L289F | Missense Mutation (SNP) | VAF 69/263 reads (26%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IGHG2 | c.386C>T p.T129I | Missense Mutation (SNP) | VAF 34/92 reads (37%) | SIFT tolerated (0.37); PolyPhen benign (0.048); called by muse, varscan2
- IGHG2 | c.332C>T p.A111V | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT tolerated (0.21); PolyPhen benign (0.003); called by muse, varscan2
- IGHG4 | c.96C>A p.Y32* | Nonsense Mutation (SNP) | VAF 5/36 reads (14%) | called by muse, mutect2, varscan2
- IGHM | c.797C>T p.A266V | Missense Mutation (SNP) | VAF 32/111 reads (29%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.691); called by muse, mutect2, varscan2
- IGHM | c.378C>A p.N126K | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT tolerated (0.89); called by muse, mutect2, varscan2
- IGHM | c.297G>T p.K99N | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT deleterious (0.01); called by muse, varscan2
- IGHM | c.58G>A p.D20N | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0.01); called by muse, mutect2
- MEF2B | c.16dup p.I6Nfs*29 | Frame Shift Ins (INS) | VAF 42/150 reads (28%) | called by mutect2, varscan2
- SMCHD1 | c.3274_3276+1del p.X1092_splice | Splice Site (DEL) | VAF 15/138 reads (11%) | called by mutect2, pindel, varscan2
- AKAP11 | c.3744C>A p.P1248= | Silent (SNP) | VAF 25/92 reads (27%) | catalogued as COSV99214061; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.525G>A p.L175= | Silent (SNP) | VAF 18/100 reads (18%) | catalogued as COSV99783733; called by muse, mutect2, varscan2
- CDH7 | c.1572T>C p.D524= | Silent (SNP) | VAF 19/161 reads (12%) | catalogued as COSV100542652; called by muse, mutect2
- CNBD1 | c.924T>A p.L308= | Silent (SNP) | VAF 19/68 reads (28%) | catalogued as COSV101582253; called by muse, mutect2, varscan2
- EIF3A | c.1080T>G p.G360= | Silent (SNP) | VAF 33/118 reads (28%) | catalogued as COSV100974670; called by muse, mutect2, varscan2
- FAM47C | c.2442G>A p.P814= | Silent (SNP) | VAF 35/67 reads (52%) | catalogued as rs1374390699, COSV100792740, COSV63726225; called by muse, mutect2, varscan2
- FOXA2 | c.1026G>A p.Q342= (on ENST00000377115 / NM_153675.3; = p.Q348= on NM_021784.5) | Silent (SNP) | VAF 20/71 reads (28%) | catalogued as rs1294444786, COSV101008406; called by muse, mutect2, varscan2
- IGHG1 | c.483C>T p.Y161= | Silent (SNP) | VAF 34/85 reads (40%) | catalogued as rs746455618; called by muse, varscan2
- IGLC2 | c.270G>A p.T90= | Silent (SNP) | VAF 42/234 reads (18%) | catalogued as rs774342214; called by muse, varscan2
- IGLV3-25 | c.75G>A p.Q25= | Silent (SNP) | VAF 42/112 reads (38%) | called by muse, mutect2, varscan2
- IGLV4-60 | c.333T>C p.Y111= | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as rs762416993, COSV101135225; called by muse, mutect2, varscan2
- KANK2 | c.1500G>A p.Q500= (on ENST00000586659 / NM_001379562.1; = p.Q508= on NM_015493.7 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 19/74 reads (26%) | catalogued as COSV100763247; called by muse, mutect2, varscan2
- MARK1 | c.144G>A p.T48= | Silent (SNP) | VAF 56/208 reads (27%) | catalogued as rs746842835, COSV100857343; called by muse, mutect2, varscan2
- MDGA1 | c.2814C>T p.S938= | Silent (SNP) | VAF 43/95 reads (45%) | catalogued as COSV99777074; called by muse, mutect2, varscan2
- MPEG1 | c.330C>T p.S110= | Silent (SNP) | VAF 42/124 reads (34%) | catalogued as COSV99915593; called by muse, mutect2, varscan2
- MYEF2 | c.666C>T p.V222= | Silent (SNP) | VAF 34/139 reads (24%) | catalogued as COSV99981799; called by muse, mutect2, varscan2
- NR3C2 | c.2895C>T p.S965= | Silent (SNP) | VAF 34/96 reads (35%) | catalogued as rs763867302, COSV60984829; called by muse, mutect2, varscan2
- OSBPL10 | c.48C>T p.S16= | Silent (SNP) | VAF 38/106 reads (36%) | catalogued as rs932860285, COSV64384881; called by muse, mutect2, varscan2
- PCDH15 | c.3483T>C p.T1161= | Silent (SNP) | VAF 28/116 reads (24%) | catalogued as rs772300262, COSV100222941; called by muse, mutect2, varscan2
- PIM1 | c.543G>A p.E181= | Silent (SNP) | VAF 19/89 reads (21%) | catalogued as COSV100998705, COSV65165102; called by muse, mutect2, varscan2
- PRKCH | c.396G>T p.V132= | Silent (SNP) | VAF 26/101 reads (26%) | catalogued as COSV100273475; called by muse, mutect2, varscan2
- RAB3GAP2 | c.3729C>T p.P1243= | Silent (SNP) | VAF 69/264 reads (26%) | catalogued as rs1209786231, COSV100741328; called by muse, mutect2, varscan2
- RASD1 | c.699C>T p.G233= | Silent (SNP) | VAF 24/85 reads (28%) | catalogued as COSV99245832; called by muse, mutect2, varscan2
- RGS6 | c.699G>A p.V233= | Silent (SNP) | VAF 19/91 reads (21%) | called by muse, varscan2
- ROS1 | c.1962A>T p.P654= | Silent (SNP) | VAF 6/150 reads (4%) | catalogued as COSV100877263; called by muse, mutect2
- TMEM54 | c.48G>A p.V16= | Silent (SNP) | VAF 19/63 reads (30%) | catalogued as COSV100231953; called by muse, mutect2, varscan2
- TRDN | c.354T>C p.D118= | Silent (SNP) | VAF 24/96 reads (25%) | catalogued as COSV100522485; called by muse, mutect2, varscan2
- VPS13A | c.2328A>T p.R776= | Silent (SNP) | VAF 51/287 reads (18%) | catalogued as COSV100653049; called by muse, mutect2, varscan2
- ZNF425 | c.1533G>A p.S511= | Silent (SNP) | VAF 27/71 reads (38%) | catalogued as rs575584712, COSV65202544; called by muse, mutect2, varscan2
- ZNF707 | c.342C>T p.A114= | Silent (SNP) | VAF 26/108 reads (24%) | catalogued as COSV100690663; called by muse, mutect2
- ZSCAN25 | c.492G>A p.G164= | Silent (SNP) | VAF 28/77 reads (36%) | catalogued as rs756255744, COSV99500621, COSV99500739; called by muse, mutect2, varscan2
- SNORD52 | chr6:31837336 G>A | 3'Flank (SNP) | VAF 66/248 reads (27%) | catalogued as COSV100794745; called by muse, mutect2, varscan2
- TGIF1 | c.-436G>A | 5'UTR (SNP) | VAF 27/210 reads (13%) | catalogued as rs765309909, COSV100394892; called by muse, mutect2, varscan2
